Surgical pathology report (de-identified scan), TCGA case TCGA-24-1413, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1413-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED]

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- HIGH GRADE SEROUS CARCINOMA
- INVOLVING THE OVARIAN PARENCHYMA AND SURFACE
- LYMPHVASCULAR SPACE INVASION PRESENT

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- DETACHED INTRALUMINAL AND PERITUBAL DEPOSITS OF HIGH GRADE SEROUS CARCINOMA
- TUBAL EPITHELIUM WITH NO HISTOPATHOLOGIC ABNORMALITY
- CYSTIC WALTHARD RESTS

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- HIGH GRADE SEROUS CARCINOMA
- INVOLVING THE OVARIAN PARENCHYMA AND SURFACE
- CORPUS LUTEUM

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- DETACHED INTRALUMINAL AND PERITUBAL DEPOSITS OF HIGH GRADE SEROUS CARCINOMA
- TUBAL EPITHELIUM WITH NO HISTOPATHOLOGIC ABNORMALITY
- CYSTIC WALTHARD RESTS

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- SQUAMOUS METAPLASIA
- CHRONIC CERVICITIS
- TUNNEL CLUSTERS

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- SECRETORY ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- HIGH GRADE SEROUS CARCINOMA BY DIRECT EXTENSION OF SEROSAL DEPOSITS
- ADENOMYOSIS, UNINVOLVED BY TUMOR
- LEIOMYOMA (0.4 CM)

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- HIGH GRADE SEROUS CARCINOMA
- ADHESIONS

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

"PELVIC TUMOR," BIOPSY (FS1)

- HIGH GRADE SEROUS CARCINOMA

SOFT TISSUE, "CUL-DE-SAC," BIOPSY

- HIGH GRADE SEROUS CARCINOMA

APPENDIX, APPENDECTOMY

- HIGH GRADE SEROUS CARCINOMA INVOLVING THE PERIAPPENDICEAL SOFT TISSUE

- FIBROUS OBLITERATION OF THE APPENDIX

SOFT TISSUE, OMENTUM, EXCISION

- HIGH GRADE SEROUS CARCINOMA

SOFT TISSUE, "PERIHEPATIC TUMOR," BIOPSY

- HIGH GRADE SEROUS CARCINOMA

History:

The patient is a [REDACTED] with ascites. Operative procedure: Exploratory laparotomy, [REDACTED]

Specimen(s) Received:

A: PELVIC TUMOR

B: RIGHT OVARY AND TUBE

C: LEFT TUBE AND OVARY

D: UTERUS, AND CERVIX

E: CULDUSAC TUMOR

F: APPENDIX

G: OMENTUM

H: PERI HEPATIC TUMOR

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

The specimens are received in eight formalin-filled containers, each labeled [REDACTED]. The first container is labeled "pelvic tumor, FS1." It contains a pink-tan friable portion of tissue measuring 8.7 x 8.6 x 2.5 cm. The surface is irregular and slightly papillary in nature. Serially sectioned to show homogeneous, tan, fleshy material. Also, there is a white plastic cassette labeled "FS1," which contains a pink-tan fragment of tissue measuring 1.7 x 1.4 x 0.3 cm. Labeled A1 (FS1); A2, A3 - representative sections. Jar 1.

The second container is labeled "right tube and ovary." It contains a pink-tan tubo-ovarian complex measuring 7.1 x 4.5 x 3.2 cm, and a separate fragment of pink-purple tissue measuring 2.7 x 2.5 x 1.6 cm. The fallopian tube measures 7.0 x 1.5 x 1.3 cm. The surface contains irregular pink-maroon papillary tissue on approximately half of the serosal surface. The associated pink-tan ovary measures 3.7 x 2.4 x 2.2 cm. The entire surface is covered by pink-tan papillary tissue. The ovary is serially sectioned to show an orange-red corpus luteum measuring 1.1 cm. The remaining ovarian parenchyma is partially composed of the pink-tan tissue, which is covering the surface. The fallopian tube is serially sectioned to show a lumen that is partially filled by red-tan papillary projections. Labeled B1 to B5 - representative sections of the fallopian tube and ovary. [REDACTED]

The third container is labeled "left tube and ovary." It contains a maroon-pink tubo-ovarian complex measuring 7.5 x 4.6 x 4.0 cm. The surface of the entire tissue is covered by pink-tan papillary projections. The different components of the specimen are hard to discern but the area thought to represent the fallopian tube measures 6.0 x 1.6 x 1.1 cm. Upon sectioning, there is a pinpoint lumen. The surface, as stated before, is covered with the pink-tan papillary projections. The area of the ovary measures 3.2 x 2.5 x 2.3 cm. Cut sections of the ovary show an orange-maroon corpus luteum measuring 1.1 cm. Labeled C1 - fallopian tube; C2, C3 - ovary; C4 to C6 - remainder of fallopian tube. [REDACTED]

The fourth container is labeled "uterus and cervix." It contains a 90 gram pear-shaped uterus measuring 9.3 x 6.9 x 5.1 cm. The serosal surface of the uterus is slightly rough with pink-tan papillary tissue on the anterior surface just above the peritoneal reflection. The ectocervix is pink-white and measures 3.4 x 3.0 cm with an oval os measuring 0.2 cm. The uterus is bisected to show an unremarkable endometrial cavity, measuring 5.0 x 1.3 cm. The endocervix measures 3.0 x 1.1 cm. The uterus is serially sectioned to show a 0.8 cm circumscribed area of white trabeculation in the posterior myometrium. The myometrium contains no other gross lesions. Labeled D1 - anterior cervix; D2 - posterior cervix; D3, D4 - anterior endomyometrium; D5, D6 - posterior endomyometrium including lesion in D6. [REDACTED]

The fifth container is labeled "cul de sac tumor." It contains multiple pink-tan fragments of tissue, aggregately measuring 5.0 x 4.0 x 2.2 cm. Most of the tissue is composed of pink-tan papillary tissue. [REDACTED]

The sixth container is labeled "appendix." It contains a red-tan vermiform appendix with periappendiceal soft tissue, measuring 5.6 x 2.6 x 1.6 cm. The majority of the surface of the appendix and the periappendiceal soft tissue is smooth and glistening. There is a 0.5 x 0.4 cm area of slightly irregular tissue. The appendix is serially sectioned to show a pinpoint lumen with no gross lesions. [REDACTED]

The seventh container is labeled "omentum." It contains multiple pink-yellow fragments of adipose tissue, aggregately measuring 27 x 14 x 6.5 cm. The surface of the omentum contains multiple areas of pink-tan papillary tissue. Sectioning the adipose tissue shows diffuse infiltration by the pink-tan papillary tumor. [REDACTED]

The eighth container is labeled "perihepatic tumor." It contains multiple fragments of pink-tan papillary tissue, aggregately measuring 5.7 x 5.0 x 1.4 cm. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The the primary tumors are the right and left ovary (synchronous primary tumors)

[page 4 of 4]
HISTOLOGIC GRADE

The histologic grade is poorly differentiated [REDACTED]

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the extrapelvic peritoneum is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis [REDACTED]

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed [REDACTED]

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed [REDACTED]

[REDACTED]

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

[REDACTED]

Source: NCI Genomic Data Commons file e2ed8d7e-aa00-4b9e-b0b2-655bf714022a (TCGA-24-1413.2CA18D08-E930-4244-A0D5-316DFBCA0FB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).